CCDI case PBBIRB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/6243a283-85d4-48fb-b9bd-d144f3e5b205

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Astrocytoma, NOS: ICD-O-3 morphology code: 9400/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 7.6 years (2,783 days).

Biospecimens (3 samples)
- Sample 0DA6QI: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DA6R1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DA6R6: Tissue type: Tumor; Specimen type: Solid Tissue.
